Somatic mutation profile of tumor specimen TCGA-IB-7649-01A (aliquot TCGA-IB-7649-01A-11D-2154-08) from TCGA case TCGA-IB-7649, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 73.3 years (26,773 days).
Specimen TCGA-IB-7649-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b253efa-6aaf-408f-830c-4e24eb2d390e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7649-10A (Blood Derived Normal), aliquot TCGA-IB-7649-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5977471a-ea7f-40b4-a02d-d9a7ee95b24e

The open-access MAF lists 38 somatic variants for this specimen: 32 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 5, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 38/468 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 72/539 reads (13%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF25 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 70/481 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs375345701; called by muse, mutect2, varscan2
- BCHE | c.820T>G p.L274V | Missense Mutation (SNP) | VAF 91/728 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1310350585, COSV100012415; called by muse, mutect2, varscan2
- BEND7 | c.593T>A p.L198Q | Missense Mutation (SNP) | VAF 85/1138 reads (7%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as COSV100346608; called by muse, mutect2
- BTAF1 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99795230; called by muse, mutect2
- CACNB1 | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 67/734 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100703382; called by muse, mutect2
- COLEC11 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs368720161; called by muse, mutect2
- DDHD1 | c.667G>A p.D223N (on ENST00000323669; = p.D420N on NM_030637.3) | Missense Mutation (SNP) | VAF 87/706 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV100079427, COSV60363446; called by muse, mutect2, varscan2
- FAT4 | c.14362G>A p.G4788R | Missense Mutation (SNP) | VAF 50/543 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138173652, COSV58704889; called by muse, mutect2
- H2BC11 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 71/1246 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100345714; called by muse, mutect2
- IGSF10 | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 44/626 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs35114212; called by muse, mutect2
- INSYN1 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 94/728 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs200967826, COSV101138754; called by muse, mutect2, varscan2
- IRAG1 | c.2731G>T p.E911* | Nonsense Mutation (SNP) | VAF 28/227 reads (12%) | catalogued as COSV101351118; called by muse, mutect2, varscan2
- LRP5 | c.3049A>T p.S1017C | Missense Mutation (SNP) | VAF 132/873 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.375); catalogued as COSV99591853; called by muse, mutect2, varscan2
- LRRN2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs771218431, COSV65784304; called by muse, mutect2
- MIDN | c.1251C>A p.H417Q | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.13); catalogued as COSV99960192; called by muse, mutect2
- MYH6 | c.1314C>G p.N438K | Missense Mutation (SNP) | VAF 38/588 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.297); catalogued as COSV100676478; called by muse, mutect2
- NBEA | c.5890A>G p.I1964V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV100079248; called by muse, mutect2
- NFAT5 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 34/636 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100590703; called by muse, mutect2
- NLGN3 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.322); catalogued as COSV62442357; called by muse, mutect2
- NLGN4X | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760432673, COSV52002990; called by muse, mutect2
- PIK3R4 | c.1385A>T p.Y462F | Missense Mutation (SNP) | VAF 81/609 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100768355; called by muse, mutect2, varscan2
- RBM10 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 15/163 reads (9%) | catalogued as COSV100237770, COSV61308772, COSV61309636; called by muse, mutect2
- RPS11 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 74/616 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54527179; called by muse, mutect2, varscan2
- SDCBP | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 47/471 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1490208880, COSV99486262; called by muse, mutect2
- SHQ1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as rs1439082018, COSV100344858, COSV57767325; called by muse, mutect2
- SPTBN2 | c.3126G>C p.E1042D | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV100019066; called by muse, mutect2, varscan2
- ZC3H12B | c.908A>T p.D303V | Missense Mutation (SNP) | VAF 50/616 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100161672; called by muse, mutect2
- ZNF653 | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 68/678 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1337519168, COSV99542092; called by muse, mutect2, varscan2
- CDKN2A | c.332_348del p.G111Afs*3 | Frame Shift Del (DEL) | VAF 23/223 reads (10%) | called by mutect2, pindel
- TMEM236 | c.226A>C p.K76Q | Missense Mutation (SNP) | VAF 187/2242 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, mutect2
- BIN1 | c.1746C>T p.G582= (on ENST00000316724 / NM_001320642.1; = p.G443= on NM_004305.4) | Silent (SNP) | VAF 40/543 reads (7%) | catalogued as rs578196295, COSV52121469; called by muse, mutect2
- ELMOD1 | c.960G>A p.A320= | Silent (SNP) | VAF 175/1001 reads (17%) | catalogued as rs764635964, COSV56192809; called by muse, mutect2, varscan2
- HTR1B | c.564T>G p.R188= | Silent (SNP) | VAF 22/534 reads (4%) | catalogued as COSV100885390; called by muse, mutect2
- KCNK3 | c.1050C>T p.G350= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100256795; called by muse, mutect2
- TTC19 | c.654A>G p.E218= | Silent (SNP) | VAF 71/490 reads (14%) | catalogued as COSV99890114; called by muse, mutect2, varscan2
- AKR7A3 | c.*2C>G | 3'UTR (SNP) | VAF 44/335 reads (13%) | catalogued as COSV100853806; called by muse, mutect2, varscan2
